Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABEN, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABEN-TTP1-A (Primary Tumor).

[page 1 of 14]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

Physician(s): [REDACTED]

Accession #: [REDACTED]

Client: [REDACTED]

Location: [REDACTED]

Acct: [REDACTED]

Copy To: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

Final Diagnosis

"Liver", image guided core biopsy- Metastatic small cell carcinoma. See note.

NOTE: The biopsy demonstrates carcinoma with a desmoplastic stroma with a small portion of residual hepatic parenchyma. The tumor grows in a trabecular fashion, with peripheral nuclear palisading. Focally, lumina are noted. The tumor cell nuclei are hyperchromatic with relatively fine chromatin. No significant nucleolar enlargement is noted. Apoptosis is prominent. Intraepithelial lymphocytes are absent. Mitotic rate is brisk (>10 mitoses/10 high power fields). Mucicarmin stain is negative for cytoplasmic mucin; mucicarminophilia is noted focally at the luminal borders when present. Immunohistochemical stains demonstrate strong diffuse immunoreactivity for cytokeratins AE1/AE3 and CAM 5.2, synaptophysin and CD56. No immunoreactivity is seen with chromogranin, cytokeratin 7, cytokeratin 20, CDX2, TTF-1 and PSA.

The histologic and immunophenotypic pattern is that of small cell carcinoma. Given the clinical features of a right abdominal mass (proved to be a right colon mass), the absence of a mass elsewhere including the lung (the tumor is TTF-1 negative), a metastasis from a primary colon small cell carcinoma is favored.

Case discussed on various occasions with [REDACTED]

Specimen(s) Submitted

"Mult liver lesions on CT [REDACTED] -3

History

? colon mass, ? met. DZ, r/o hepatic CA, CA pancreatic hx. family, jaundice, abd. pain

Gross Description

The specimen is received in formalin, labeled with patient name [REDACTED] and designated "CT liver biopsy". It consists of two opaque to tan cylindrical soft tissue fragment(s) measuring 1.6 x 0.1 x 0.1 and 1.6 x 0.1 x 0.1 cm. Entire, 1 block(s).

[page 2 of 14]
[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT [REDACTED] [REDACTED]

The block is subsequently divided into A & B with one core in each block after initial H&E preparation (original slides will have both core samples on slides and special studies will have one core per slide). This protocol will enhance tissue conservation allowing for maximum special study material.

[REDACTED]

[REDACTED]

[page 3 of 14]
SURGICAL PATHOLOGY REPORT

Patient Name:

Accession #:

Med. Rec. #:

DOB:

Gender:

Physician(s):

Client:

Location:

Acct:

Copy To:

Taken:

Received:

Reported:

Final Diagnosis

"Colon mass", biopsy- Small cell carcinoma. See note.

NOTE: The specimen consists primarily of nonneoplastic colonic mucosa. In a few small foci, there are aggregates of cells with round to short spindled nuclei with nuclear hyperchromasia, relatively fine chromatin, absent nucleoli, prominent apoptosis and crush artefact in the lamina propria and muscularis mucosae. These cells are strongly and diffusely positive for cytokeratins AE1/AE3 and CAM 5.2 and synaptophysin and are negative for CD45, TTF-1 and chromogranin. The histologic and immunophenotypic features are those of small cell carcinoma. The patient's prior liver core biopsy was reviewed [REDACTED]. The nuclear features of the tumor cells and the immunophenotype are identical, although the architectural pattern varies at the two sites. This likely is related to sampling variation. The clinicopathologic features favor a colon primary small cell carcinoma. These tumors are rare (<1% colorectal malignancies) and do not appear to be associated with hereditary nonpolyposis colorectal cancer (HNPCC). Nearly all of the relatively few cases studied have had intact mismatch repair (MMR) proteins indicating they likely evolve through a chromosomal instability pathway rather than microsatellite instability (MSI).

Case discussed with [REDACTED]

+5

Specimen(s) Submitted

"Colon mass"

History

Please send for MSI testing

Pre-operative Diagnosis

Liver CA, R/O colon CA

Post-operative Diagnosis

Colon mass

[page 4 of 14]
[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT [REDACTED]

Gross Description

The specimen is received in formalin, labeled with patient name [REDACTED] and designated "colon mass". It consists of multiple pink-tan to red soft tissue fragment(s) measuring in aggregate 0.8 x 0.6 x 0.2 cm. Entire, 1 block(s).

[REDACTED]

[page 5 of 14]
PATIENT NAME:

DOB:

ADDRESS:

PHONE:

M. R. NO:

HOSP SVC:

ORDERING DR:

CLIN HISTORY:

AGE: 50Y

SEX:

M

LOCATION:

ACCESSION NO:

PT. CLASS:

E

ATTENDING DR:

PRIMARY CARE DR:

PT ADM NO:

FINAL REPORT

ULTRASOUND

ABDOMEN COMPLETE US -3

COMMENTS: CLINICAL INDICATION: Abdominal pain

Real-time ultrasound examination of the abdomen was performed. The liver is enlarged at 24 cm in length and is markedly abnormal in echotexture. It is diffusely heterogeneous with what appear to be multiple coalescing hypoechoic lesions.. The gallbladder is normal in size. It contains numerous calculi.. The ductal system is normal in caliber. The pancreas is obscured by bowel gas.. Scanned in left upper quadrant show hypertrophied left lobe of liver and spleen was not visualized. Images of both kidneys were obtained. There is no hydronephrosis . The aorta and inferior vena cava are unremarkable.

IMPRESSION: Markedly abnormal liver. CT scan is recommended for further assessment.

CPT CODE:

Printed: <date>

Page 1

[page 6 of 14]
PATIENT NAME:

DOB:

ADDRESS:

PHONE:

M. R. NO:

HOSP SVC:

ORDERING DR:

CLIN HISTORY: ABDOMINAL PAIN, HEPATOMEG

AGE: 50Y

SEX:

LOCATION:

ACCESSION NO:

PT. CLASS:

ATTENDING DR:

PRIMARY CARE DR

PT ADM NO:

M

FINAL REPORT

CAT SCAN

CT ABD PEL W (OS)

-3

COMMENTS: CLINICAL INDICATION: abnormal liver on ultrasound

CT examination of the abdomen and pelvis was performed following administration of oral contrast as well as intravenous injection of 100 cc of Omnipaque-300. Bowel opacification is suboptimal.

The liver is enlarged and contains multiple low attenuation lesions, most consistent with diffuse metastatic disease. Gallbladder is contracted. There are high attenuation foci in the gallbladder region consistent with small calculi. There is no ductal dilatation. The spleen is normal in appearance. The adrenal glands are normal in size and contour.

There is a 7 cm poorly circumscribed soft tissue mass in the right lower quadrant. This is in the region of cecum. Colon is not contrast opacified. This lesion is very heterogeneous with low attenuation areas centrally. There are numerous soft tissue nodules seen in the peritoneal cavity anterior to this. Extending medially from the larger mass is a similar-appearing soft tissue mass which is measured at 4 cm in diameter. Midline there is a soft tissue mass anterior to the duodenum which measures 2.7 cm in diameter. Nodes in the aortocaval region measure up to 1.2 cm in diameter. Moderate amount of soft tissue is seen peripancreatic region. While some of this may represent unopacified small bowel I suspect there is additional adenopathy in this region. There is a small amount of free fluid seen lateral to the mass in the right lower quadrant and in cul-de-sac. The small bowel proximal to the large mass is contrast-filled and not distended. The colon more distally is relatively small. It does contain air and fecal material.

Kidneys are unremarkable in appearance. The right is normal in caliber. Bladder, prostate and seminal vesicles are unremarkable.

There subsegmental atelectasis at the right base. No obvious pulmonary nodules are seen. No osseous lesions are evident.

IMPRESSION: Extensive metastatic disease in the liver. There is a large heterogeneous soft tissue mass in the right lower quadrant with additional mass medially, adenopathy and numerous nodules seen of the in the omentum.

CPT CODE:

Printed: <date>

Page 1

[page 7 of 14]
[REDACTED]

PATIENT NAME:

DOB:

ADDRESS:

PHONE:

M. R. NO:

HOSP SVC:

ORDERING DR:

CLIN HISTORY:

AGE: 50Y

SEX:

M

LOCATION:

ACCESSION NO:

PT. CLASS:

ATTENDING DR:

PRIMARY CARE DR:

PT ADM NO:

[REDACTED]

Printed: <date>
Page 2

[page 8 of 14]
PATIENT NAME: [REDACTED]

DOB: [REDACTED]

ADDRESS: [REDACTED]

PHONE: [REDACTED]

M. R. NO: [REDACTED]

HOSP SVC: [REDACTED]

ORDERING DR: [REDACTED]

CLIN HISTORY: [REDACTED]

AGE: 50Y

SEX: [REDACTED]

LOCATION: [REDACTED]

ACCESSION NO: [REDACTED]

PT, CLASS: [REDACTED]

ATTENDING DR: [REDACTED]

PRIMARY CARE DR: [REDACTED]

PT ADM NO: [REDACTED]

M

FINAL REPORT

CAT SCAN

NEEDLE BIOPSY LIVER CT [REDACTED] -2

COMMENTS: Clinical History: Cecal mass. Multiple low density lesions throughout the liver. Biopsy is needed for tissue diagnosis.

Patient's prior images are reviewed. Informed consent was obtained for CT guided liver biopsy. Patient was placed on CT examination table in supine position. Monitored conscious sedation was administered for a period of 1/2 hour. Localization imaging was performed. Mass in the right hepatic lobe is identified. The overlying skin was prepped and draped in sterile fashion. Following local anesthesia, 17 gauge introducer needle was advanced into the periphery of the lesion under CT guidance. After confirming adequate needle positioning, multiple 18 gauge core specimens of the lesion were obtained in coaxial fashion. Specimen was placed in 10% formalin solution and processed for surgical pathology. Postbiopsy imaging was performed. This showed no change in the appearance of the lesion and no evidence of perihepatic bleeding. The patient tolerated the procedure well. No complications were encountered.

IMPRESSION: Uneventful CT guided biopsy of a mass in the right hepatic lobe.

CPT CODE: [REDACTED]

Printed: <date>

Page 1

[page 9 of 14]
PATIENT NAME:

DOB:

ADDRESS:

PHONE:

M. R. NO:

HOSP SVC:

ORDERING DR:

CLIN HISTORY:

AGE: 51Y

SEX:

M

LOCATION:

ACCESSION NO:

PT. CLASS:

ATTENDING DR:

PRIMARY CARE DR:

PT ADM NO:

FINAL REPORT

CT CHEST ABD PEL W (OS) +237

COMMENTS: STUDY: CT of the CHEST and ABDOMEN and PELVIS after the uneventful intravenous administration of 100 cc of Omnipaque 350. Oral contrast was also used.

INDICATION: Colon cancer

COMPARED WITH: CT of the chest, abdomen, pelvis performed on +153

CHEST

LUNG AND AIRWAYS: The airways appear widely patent throughout. There is minimal bibasilar atelectasis. There is stable focal nodular scarring along the right major fissure inferiorly on image #40 of series 5. Additional similar finding superiorly on image #32. No other discrete lung nodule or mass.

PLEURA: No pleural effusion or pneumothorax.

VESSELS: Atherosclerotic changes in the aorta and coronary arteries.

HEART: normal size. No pericardial effusion.

MEDIASTINUM AND HILA: A few scattered subcentimeter mediastinal lymph nodes. No lymphadenopathy by size criteria.

CHEST WALL AND LOWER NECK: Grossly normal thyroid gland. No significant supraclavicular or axillary lymphadenopathy.

ABDOMEN:

LIVER: The previously seen scattered tiny low attenuating lesions have resolved. There is a small stable possible cyst or hemangioma adjacent to the gallbladder fossa.

BILE DUCTS: normal caliber.

GALLBLADDER: No calcified gallstones. Normal caliber wall.

PANCREAS: within normal limits.

SPLEEN: Small accessory splenule.

ADRENALS: within normal limits.

KIDNEYS: Within normal limits. No hydronephrosis or perinephric stranding.

PELVIS:

REPRODUCTIVE ORGANS: Normal sized prostate gland. Symmetric seminal vesicles.

URETERS: within normal limits.

BLADDER: Improvement in the bladder wall thickening.

Printed: <date>

Page 1

[page 10 of 14]
PATIENT NAME:

DOB:

ADDRESS:

PHONE:

M. R. NO:

HOSP SVC:

ORDERING DR:

CLIN HISTORY:

AGE: 51Y

SEX:

M

LOCATION:

ACCESSION NO:

PT. CLASS:

ATTENDING DR:

PRIMARY CARE DR:

PT ADM NO:

BOWEL: Normal caliber throughout. Small amount of stool seen throughout the colon. Diverticulosis coli without CT evidence of diverticulitis. No focal wall thickening. Normal appendix. No enlarged mesenteric lymph nodes.

PERITONEUM: no ascites or free air, no fluid collection.

VESSELS: Atherosclerotic changes.

RETROPERITONEUM: No enlarged retroperitoneal or pelvic nodes.

ABDOMINAL WALL: Small fat containing left inguinal hernia.

BONES: Degenerative changes.

IMPRESSION:

1. No significant lymphadenopathy within the chest, abdomen, or pelvis.
2. The previously seen multiple hepatic lesions have resolved in the interim. There is a small probable stable cyst or hemangioma within the right lobe of the liver adjacent to the gallbladder fossa.
3. Diverticulosis coli without CT evidence of diverticulitis.

CPT CODE:

Printed: <date>

Page 2

[page 11 of 14]
PATIENT NAME:

DOB:

ADDRESS:

PHONE:

M. R. NO:

HOSP SVC:

ORDERING DR:

CLIN HISTORY:

AGE: 51Y

SEX:

M

LOCATION:

ACCESSION NO:

PT. CLASS:

ATTENDING DR:

PRIMARY CARE DR:

PT ADM NO:

FINAL REPORT

CT CHEST ABD PEL W (OS) +307

COMMENTS: History: Colon cancer. Followup.

Findings: CT scan of the thorax, abdomen and pelvis was performed on a 6 slice scanner following the administration of 125 cc of intravenous Omnipaque 350 and oral contrast material. Comparison is made with prior study dated

The thyroid gland is homogeneous. Subcentimeter mediastinal lymph nodes are stable. There is no significant hilar or axillary lymphadenopathy. The thoracic aorta is not aneurysmal.

There are no pleural or pericardial effusions. Tiny focal pleural scars are stable on series 5 image 42 and a second similar finding is stable on image 33. There are no suspicious pulmonary nodules.

Previously described small cyst or hemangioma measures 8mm and is stable adjacent to the gallbladder fossa on series 3 image 26. There are no suspicious focal hepatic lesions. There are no calcified gallstones. There is no biliary dilatation.

Spleen, pancreas, adrenal glands and kidneys demonstrate no focal mass. There is no hydronephrosis.

The opacified segments of bowel demonstrate no wall thickening. There is uncomplicated diverticulosis.

Subcentimeter retroperitoneal lymph nodes are stable. There is no significant mesenteric lymphadenopathy.

The bladder demonstrates normal contour. Seminal vesicles and prostate gland are grossly normal. Small inguinal lymph nodes are stable. There are no pathologically enlarged pelvic lymph nodes.

There are no suspicious lytic or blastic lesions involving the osseous structures.

IMPRESSION:

No evidence of metastatic disease within the chest, abdomen and pelvis. Subcentimeter probable cyst or hemangioma is stable adjacent to the gallbladder fossa.

Uncomplicated diverticulosis.

CPT CODE:

Printed: <date>
Page 1

[page 12 of 14]
[REDACTED]

PATIENT NAME:

DOB:

ADDRESS:

PHONE:

M. R. NO:

HOSP SVC:

ORDERING DR:

CLIN HISTORY:

AGE: 51Y

SEX:

M

LOCATION:

ACCESSION NO:

PT. CLASS:

ATTENDING DR:

PRIMARY CARE DR:

PT ADM NO:

[REDACTED]

Printed: <date>
Page 2

[page 13 of 14]
PATIENT NAME: [REDACTED]

DOB: [REDACTED]

ADDRESS: [REDACTED]

PHONE: [REDACTED]

M. R. NO: [REDACTED]

HOSP SVC: [REDACTED]

ORDERING DR: [REDACTED]

CLIN HISTORY: [REDACTED]

AGE: 55Y

SEX: M

LOCATION: [REDACTED]

ACCESSION NO: [REDACTED]

PT. CLASS: [REDACTED]

ATTENDING DR: [REDACTED]

PRIMARY CARE DR: [REDACTED]

PT ADM NO: [REDACTED]

FINAL REPORT

CT CHEST ABD PEL W (OS/NON) [REDACTED] +1987

COMMENTS: STUDY: CT of the CHEST and ABDOMEN and PELVIS after the uneventful intravenous administration of 100 cc of Omnipaque 350. Oral contrast was also used.

INDICATION: Colon cancer

COMPARED WITH: CT the chest, abdomen, pelvis performed on [REDACTED] +1805

CHEST

LUNG AND AIRWAYS: The airways appear widely patent throughout. There is minimal posterior and bibasilar dependent atelectasis. There is minimal atelectasis within the right middle lobe and lingula. There is a stable 0.4 cm right major fissure nodule on

image #27 of series 4. Additional stable 0.4 cm right major fissure nodule in image #36. There is a tiny stable 0.3 cm peripheral nodule within the left lower lobe on image #38. There is no new lung nodule or mass.

PLEURA: No pleural effusion or pneumothorax.

VESSELS: Atherosclerotic changes in the aorta and coronary arteries. There is a stable ascending thoracic aneurysm measuring 4.1 x 4.0 cm in diameter.

HEART: normal size. No pericardial effusion.

MEDIASTINUM AND HILA: A few small subcentimeter mediastinal and hilar lymph nodes. There is no lymphadenopathy by size criteria.

CHEST WALL AND LOWER NECK: No significant supraclavicular or axillary lymphadenopathy.

ABDOMEN:

LIVER: Minimal diffuse fatty infiltration.

BILE DUCTS: normal caliber.

GALLBLADDER: Small calcified gallstones. No significant wall thickening or distention.

PANCREAS: within normal limits.

SPLEEN: Mildly enlarged measuring 13.4 cm in length in the AP dimension.

ADRENALS: within normal limits.

KIDNEYS: Mild nonspecific bilateral perinephric stranding. No hydronephrosis.

PELVIS:

REPRODUCTIVE ORGANS: Normal size prostate gland with internal calcifications. Symmetric seminal vesicles.

URETERS: within normal limits.

BLADDER: Mild apparent diffuse wall thickening may be related to chronic outlet obstruction and/or cystitis.

Printed: [REDACTED]
Page 1

[page 14 of 14]
PATIENT NAME:

DOB:

ADDRESS:

PHONE:

M. R. NO:

HOSP SVC:

ORDERING DR:

CLIN HISTORY:

AGE: 55Y

SEX:

M

LOCATION:

ACCESSION NO:

PT. CLASS:

ATTENDING DR:

PRIMARY CARE DR:

PT ADM NO:

BOWEL: Normal caliber throughout. There is no significant bowel wall thickening. No definite evidence of local tumor recurrence. Diverticulosis coli without CT evidence of diverticulitis. Normal appendix. A few small subcentimeter mesenteric root lymph

nodes. There is no lymphadenopathy by size criteria.

PERITONEUM: no ascites or free air, no fluid collection.

VESSELS: Atherosclerotic changes .

RETROPERITONEUM: No enlarged retroperitoneal or pelvic nodes.

ABDOMINAL WALL: Small fat-containing bilateral inguinal hernias.

BONES: Degenerative changes.

IMPRESSION: 1. Stable small likely benign lung nodules as discussed above. Continued follow-up is recommended.

2. Stable ascending thoracic aortic aneurysm.

3. Minimal diffuse fatty infiltration of the liver.

4. Cholelithiasis.

5. Mild splenomegaly.

6. Mild nonspecific bilateral perinephric stranding. No hydronephrosis.

7. Possible chronic outlet obstruction of the urinary bladder and/or cystitis.

8. No significant colonic wall thickening to suggest local tumor recurrence.

9. Bilateral inguinal hernias.

CPT CODE:

Printed:

Page 2

Source: NCI Genomic Data Commons file 738a9799-4178-45ac-8d5a-8b41e04e350b (ER0095 ER-ABEN Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).